Somatic mutation profile of tumor specimen TCGA-DC-6154-01A (aliquot TCGA-DC-6154-01A-31D-1924-10) from TCGA case TCGA-DC-6154, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Age at diagnosis: 57.7 years (21,093 days).
Specimen TCGA-DC-6154-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5dce652-8769-49ae-ad77-bd0b6a931afe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-6154-10A (Blood Derived Normal), aliquot TCGA-DC-6154-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01018daa-ec69-47e3-af7b-1cb5002ce9ea

The open-access MAF lists 110 somatic variants for this specimen: 77 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 30, Nonsense Mutation 6, Intron 1, Frame Shift Del 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4057G>T p.E1353* | Nonsense Mutation (SNP) | VAF 19/21 reads (90%) | hotspot (GDC flag); catalogued as rs1114167568, CD972008, CM130060, COSV57321750, COSV57332693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GALT | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs111033686, CM950547; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 21/22 reads (95%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs782550135, COSV54357738; called by muse, mutect2, varscan2
- ADAMTS3 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs373312832, COSV54387019; called by muse, mutect2, varscan2
- ADAMTSL1 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52821580, COSV52823060; called by muse, mutect2, varscan2
- ADD3 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV53324887; called by muse, mutect2, varscan2
- ADGRB1 | c.3469G>A p.V1157I | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.92); PolyPhen benign (0.018); catalogued as rs371441422; called by muse, mutect2, varscan2
- ADGRG4 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as COSV54963566; called by muse, mutect2, varscan2
- AK4 | c.510G>T p.R170S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV59198842; called by muse, mutect2, varscan2
- ALB | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV55741006; called by muse, mutect2, varscan2
- ANK1 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV55877070, COSV55891081; called by muse, mutect2, varscan2
- ARMH4 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs762620810, COSV50769740; called by muse, mutect2, varscan2
- ASTN1 | c.3574C>A p.L1192I | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.367); catalogued as COSV62492158, COSV62502715; called by muse, mutect2, varscan2
- ATP2B3 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs924902616, COSV54842708; called by muse, mutect2, varscan2
- ATP8B2 | c.1280C>T p.T427M (on ENST00000672630; = p.T394M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1427625409, COSV59247791; called by muse, mutect2, varscan2
- BTNL2 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); catalogued as COSV66631661; called by muse, mutect2, varscan2
- CDH9 | c.942C>A p.D314E | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV99150114; called by muse, mutect2, varscan2
- CENPF | c.4957C>T p.R1653W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs569229505, COSV65277817; called by muse, mutect2, varscan2
- CHST11 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448807477, COSV57991332; called by muse, mutect2, varscan2
- COL1A2 | c.2380C>T p.R794W | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759251034, COSV51963558; called by muse, mutect2, varscan2
- DISP3 | c.130T>C p.C44R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as rs1382673902, COSV53834617; called by muse, mutect2
- DOCK8 | c.5800G>A p.V1934I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); catalogued as rs781705709, COSV66619766; called by muse, mutect2, varscan2
- EML5 | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV61350265; called by muse, mutect2, varscan2
- ETS2 | c.1144A>G p.I382V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100711342; called by muse, mutect2
- FAM180A | c.204C>A p.S68R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as COSV100647215; called by muse, mutect2, varscan2
- FAM47A | c.1160T>G p.L387R | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60498985; called by muse, mutect2, varscan2
- FAM90A1 | c.1009G>T p.A337S | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.095); catalogued as COSV56712500, COSV56714018; called by muse, mutect2, varscan2
- FAT4 | c.10068G>T p.Q3356H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58698768; called by muse, mutect2, varscan2
- FAXC | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV101067198; called by muse, mutect2, varscan2
- FGF23 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as COSV52975820; called by muse, mutect2, varscan2
- GLYAT | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.679); catalogued as COSV53540227; called by muse, mutect2, varscan2
- GRM7 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as rs767400612, COSV63134452; called by muse, mutect2, varscan2
- H1-5 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs780574435, COSV58901041; called by muse, mutect2, varscan2
- HOXC8 | c.314A>C p.E105A | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV99236907; called by muse, mutect2, varscan2
- INVS | c.1100C>A p.S367Y | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV52447322; called by muse, mutect2, varscan2
- ITGA10 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs369985596; called by muse, mutect2, varscan2
- ITGAM | c.3272G>A p.R1091K (on ENST00000648685 / NM_001145808.2; = p.R1090K on NM_000632.4) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99792849; called by muse, mutect2, varscan2
- KCNIP4 | c.252G>T p.K84N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100749632; called by muse, mutect2, varscan2
- KIAA0753 | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.09); catalogued as rs1343747001, COSV100810663; called by muse, mutect2, varscan2
- MEGF10 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.95); catalogued as COSV99175211; called by muse, mutect2, varscan2
- MPP2 | c.487C>T p.R163C (on ENST00000461854 / NM_001278372.2; = p.R139C on NM_005374.5) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs757493946, COSV99290631; called by muse, mutect2, varscan2
- MUC16 | c.30209C>T p.T10070I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as rs577699787, COSV67456900, COSV67463504; called by muse, mutect2, varscan2
- MYO6 | c.1049T>C p.I350T | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs377470568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCKAP1L | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs180951280; called by muse, mutect2, varscan2
- NETO1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.117); catalogued as rs201017882, COSV55001415; called by muse, mutect2, varscan2
- NLGN1 | c.1417G>T p.A473S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64342657; called by muse, mutect2, varscan2
- NLRX1 | c.2918C>A p.S973Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.123); catalogued as COSV52707825; called by muse, mutect2, varscan2
- OR1F1 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs751283450, COSV100484508, COSV58961993; called by muse, mutect2, varscan2
- OR8H3 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as COSV57910577, COSV57911785; called by muse, mutect2, varscan2
- PASD1 | c.2069T>C p.I690T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.708); catalogued as COSV64856931; called by muse, mutect2, varscan2
- PDIA3 | c.316T>C p.F106L | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as rs779107688, COSV55857710; called by muse, mutect2, varscan2
- PHF20L1 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as rs1429117928, COSV55192271; called by muse, mutect2, varscan2
- PLD3 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as rs1325388394, COSV100735251; called by muse, varscan2
- POM121C | c.2707G>A p.A903T (on ENST00000607367; = p.A661T on NM_001099415.3) | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782333810; called by muse, varscan2
- PPP1R13B | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.375); catalogued as COSV52455085; called by muse, mutect2, varscan2
- RNF14 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as rs762141519, COSV61662742; called by muse, mutect2, varscan2
- RNF40 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.742); catalogued as rs759164445, COSV61216105; called by mutect2, varscan2
- RTEL1 | c.363G>T p.Q121H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58899255; called by muse, mutect2, varscan2
- RTL9 | c.3083C>A p.S1028Y | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV71826097; called by muse, mutect2, varscan2
- SAFB | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV52653177; called by muse, mutect2, varscan2
- SEMA4B | c.1790A>G p.E597G | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV100153359; called by muse, mutect2
- SLC17A4 | c.533T>G p.V178G | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100930649; called by muse, mutect2, varscan2
- SORCS1 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as rs376036249, COSV53892494; called by muse, mutect2, varscan2
- STAT2 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs780748121, COSV58476302; called by muse, mutect2, varscan2
- TENT5D | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV57638437; called by mutect2, varscan2
- TET1 | c.6347A>G p.N2116S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.414); catalogued as rs757251233, COSV65387959; called by muse, mutect2, varscan2
- TMA16 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); catalogued as COSV99922107; called by muse, mutect2, varscan2
- TUSC3 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV65882399; called by muse, mutect2, varscan2
- UPK3A | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as rs781151893, COSV99343188; called by muse, mutect2, varscan2
- USH2A | c.350A>T p.H117L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56413699; called by muse, mutect2, varscan2
- WDR33 | c.1952G>T p.G651V | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV59253969; called by muse, mutect2, varscan2
- WDR62 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54338208; called by muse, mutect2, varscan2
- ZFPM2 | c.3294G>T p.E1098D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV65875215; called by muse, mutect2, varscan2
- IGKV1D-13 | c.119G>T p.R40I | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- SIK2 | c.261_262del p.E87Dfs*19 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | called by pindel, varscan2
- ACTR8 | c.558C>T p.I186= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV51638019; called by muse, mutect2, varscan2
- ADAMTS2 | c.3624C>T p.L1208= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as rs139420412, COSV52372834; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADCY5 | c.3237C>T p.N1079= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV59201100, COSV59202205; called by muse, mutect2, varscan2
- AMOTL1 | c.2145G>A p.T715= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as rs775640887, COSV58569289; called by muse, mutect2, varscan2
- CPVL | c.510C>A p.V170= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV55306412; called by muse, mutect2, varscan2
- CTNNA3 | c.960G>A p.T320= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV65609538; called by muse, mutect2, varscan2
- CTNND1 | c.966A>G p.E322= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV100650212; called by muse, mutect2
- CTSK | c.48G>A p.L16= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1334935822, COSV55011512, COSV99648888; called by muse, mutect2
- E2F3 | c.1263G>A p.P421= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs773205736, COSV60899159; called by muse, mutect2, varscan2
- ERMARD | c.780G>T p.V260= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV64649874; called by muse, mutect2, varscan2
- FAM9B | c.486C>T p.F162= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs140708668, COSV59118965; called by muse, mutect2, varscan2
- GIGYF2 | c.738G>A p.R246= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV65252339; called by muse, mutect2, varscan2
- GJA1 | c.873C>T p.G291= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs767963064, COSV57000213; called by muse, mutect2, varscan2
- IGHG1 | c.147C>T p.G49= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs767764840; called by muse, mutect2
- LAMA4 | c.267C>T p.N89= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as rs727503114, COSV54569660, COSV54570762; ClinVar: likely benign; called by muse, mutect2, varscan2
- LIF | c.321C>T p.R107= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV50777069; called by muse, mutect2, varscan2
- LRWD1 | c.1395C>T p.G465= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs752816875, COSV52961685; called by muse, mutect2, varscan2
- MRGPRX4 | c.138G>A p.A46= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as COSV58589924; called by muse, mutect2, varscan2
- NGF | c.159C>T p.S53= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs376241395, COSV65688511; ClinVar: likely benign; called by mutect2, varscan2
- OR5T2 | c.744C>A p.V248= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV57590442; called by muse, mutect2, varscan2
- PCDH15 | c.1539C>A p.S513= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV57350219; called by muse, mutect2, varscan2
- PCDHGA11 | c.330C>T p.L110= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs764010392, COSV54004515; called by muse, mutect2, varscan2
- PCDHGB5 | c.1611G>A p.A537= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV54004508; called by muse, mutect2, varscan2
- PLEC | c.13158G>A p.S4386= (on ENST00000322810 / NM_201380.4; = p.S4276= on NM_000445.5) | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs782377686, COSV59676493; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POC1B | c.1236C>T p.D412= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV57967480; called by muse, mutect2, varscan2
- SSTR4 | c.225C>T p.Y75= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs764351229, COSV54799531; called by muse, mutect2, varscan2
- TNFRSF13B | c.105C>T p.P35= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs200868537, CD153877; ClinVar: likely benign; called by mutect2, varscan2
- TSPYL2 | c.1488C>T p.N496= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs145686100, COSV64921384; called by muse, mutect2, varscan2
- TTN | c.66204G>A p.R22068= (on ENST00000591111; = p.R14644= on NM_003319.4) | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV60249792; called by muse, mutect2
- UBR4 | c.1089G>A p.T363= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1466508566, COSV100921391; called by muse, mutect2, varscan2
- MAP2 | c.5074-2110G>T | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99561163; called by muse, mutect2, varscan2
- NLRX1 | c.*473C>T | 3'UTR (SNP) | VAF 7/104 reads (7%) | catalogued as rs1234797596, COSV99424632; called by muse, mutect2
- NPAS3 | chr14:33801110 G>T | 3'Flank (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
